Surgical pathology report (de-identified scan), TCGA case TCGA-G5-6235, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G5-6235-01A (Primary Tumor).

[page 1 of 2]
- A. SIGMOID COLON UPPER RECTUM
B. PROXIMAL DONUT
C. DISTAL DONUT

DIAGNOSIS:

- A. COLON, RECTOSIGMOID, RESECTION:
- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA.
- TUMOR IS 3.5 CM IN GREATEST DIMENSION.
- TUMOR INFILTRATES INTO SUBSEROA.
- RADIAL MARGIN IS FOCALLY INVOLVED BY CARCINOMA (MICROSCOPIC).
- PROXIMAL AND DISTAL MARGINS ARE NEGATIVE FOR CARCINOMA.
- 1 OUT OF 13 LYMPH NODES-POSITIVE FOR CARCINOMA (1/13).
- SEE TEMPLATE.
- B. COLON, PROXIMAL DONUT, EXCISION:
- BENIGN COLONIC-TYPE MUCOSA.
- C. COLON, DISTAL DONUT, EXCISION:
- BENIGN COLONIC-TYPE MUCOSA.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Rectal/rectosigmoid colon
Tumor Site:	Rectosigmoid
Tumor Configuration:	Infiltrative, Ulcerating
Tumor Size:	3.5 x 3.0 x 0.7 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	Moderately differentiated
Extent of Invasion:	Subserosa
Margins:	Margins involved by invasive carcinoma: radial margin (focal and microscopic)
Venous/Lymphatic Invasion:	Absent
Perineural Invasion:	Absent
Extent of Resection:	Grossly negative but microscopically positive (radial margin)
Lymph Nodes:	Positive (1/13), no extranodal extension
Implants:	Absent
Pathologic Stage:	pT3c/d N1 Mx

SPECIMEN(S):

- A. SIGMOID COLON UPPER RECTUM B. PROXIMAL DONUT C. DISTAL DONUT

CLINICAL HISTORY:

Not given.

GROSS DESCRIPTION:

- A. SIGMOID COLON UPPER RECTUM

Received fresh labeled with the patient's name, and "sigmoid colon, upper rectum", is a 15.5 cm in length segment of colon and rectum. The rectal portion measures 4.5 cm. The proximal colonic margin and rectal distal margins are closed by staples. The proximal margin is inked blue and the distal margin is inked yellow. The specimen is opened and a 14 cm in length unremarkable tan-yellow mesentery is present along the colonic portion. The staples are removed and the specimen is opened to reveal that the specimen is 4 cm in circumference at the sigmoid margin and 7 cm in circumference at the rectal margin. There is a 3.5 x 3 x 0.7 cm ulcerated tumor arising at the rectosigmoid junction. The tumor attached invaded into, but not through, the muscularis propria. The tumor is located 2.8 cm from the rectal margin and 9.7 cm from the proximal colonic margin. The lumen is narrowed to 2.8 cm at the tumor region. The remainder of the mucosal surface is unremarkable. Six firm lymph nodes are

[page 2 of 2]
[REDACTED]

present in the pericolic soft tissue, the largest measuring 0.5 cm in greatest dimension. Sections of the specimen are submitted as follows:

- A1: proximal (inked blue) and distal (inked yellow) margins
- A2-3: tumor and deep margin (one section)
- A4: tumor and deep margin
- A5: tumor and rectum
- A6: tumor and colon
- A7: normal appearing rectal mucosa
- A8: normal appearing colonic mucosa
- A9: four lymph nodes
- A10: two lymph nodes

B. PROXIMAL DONUT

Received in formalin container labeled with the patient name and "proximal donut" is a 2 x 1.8 x 0.8 cm ring shaped portion of colon. There is a blue suture running around the specimen. No tumor is seen grossly. Half of the specimen is submitted in cassette B1.

C. DISTAL DONUT

Received in formalin container labeled with the patient name and "distal donut" is a 2.5 x 1.3 x 0.7 cm crescent shaped portion of colon. There is a blue suture running in the specimen. Half of the specimen is submitted in cassette C1.

[REDACTED]

Source: NCI Genomic Data Commons file 33247dda-df71-403c-a2dc-457e5368c42f (TCGA-G5-6235.A89FCB7B-EB4C-4034-BC46-4398F7BF6C52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).